Somatic mutation profile of tumor specimen TCGA-UL-AAZ6-01A (aliquot TCGA-UL-AAZ6-01A-11D-A41F-09) from TCGA case TCGA-UL-AAZ6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.9 years (26,999 days).
Specimen TCGA-UL-AAZ6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f990260-7dea-4f73-b585-aa5f9d9deab9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UL-AAZ6-10A (Blood Derived Normal), aliquot TCGA-UL-AAZ6-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be4aa5a0-1c99-4b62-acf0-74640c9aef59

The open-access MAF lists 95 somatic variants for this specimen: 65 protein-altering or splice-affecting, 24 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 24, Nonsense Mutation 4, Intron 3, Frame Shift Ins 3, Splice Region 2, Splice Site 2, 5'Flank 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.1680G>T p.V560= | Splice Region (SNP) | VAF 16/67 reads (24%) | catalogued as COSV99908265; called by muse, mutect2, varscan2
- AASDH | c.1996A>C p.I666L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs773718786, COSV99221785; called by muse, mutect2, varscan2
- ADGRV1 | c.6801T>A p.N2267K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as COSV101316436; called by muse, mutect2, varscan2
- ALDH3B2 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV62427621; called by muse, mutect2
- ANAPC5 | c.2164C>G p.H722D | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs747383939, COSV99946445; called by muse, mutect2
- BARHL2 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV100966104; called by muse, mutect2, varscan2
- BCL6 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99216016; called by muse, mutect2, varscan2
- BCL7C | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs138503357; called by muse, mutect2, varscan2
- BRWD3 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs991776603, COSV100956477; called by muse, mutect2
- C1QTNF1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs758961252, COSV59263078; called by muse, varscan2
- CACHD1 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99263197; called by muse, mutect2, varscan2
- CACNA1E | c.4391G>C p.R1464T | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100704988; called by muse, mutect2
- CAPN12 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as rs991065631, COSV100185512; called by muse, mutect2
- CCDC124 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1039237258, COSV101506512; called by muse, mutect2, varscan2
- CDX2 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.503); catalogued as COSV101122712; called by muse, mutect2, varscan2
- CHRM5 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.645); catalogued as COSV101272043; called by muse, mutect2
- CST8 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99850076; called by muse, mutect2, varscan2
- EAPP | c.374dup p.K126Efs*10 | Frame Shift Ins (INS) | VAF 37/70 reads (53%) | catalogued as rs1257825851; called by mutect2, varscan2
- ERBB4 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.54); catalogued as COSV99631735; called by muse, mutect2, varscan2
- FAM180A | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100647332, COSV58528790; called by muse, mutect2, varscan2
- FGF8 | c.286G>C p.E96Q (on ENST00000344255 / NM_033164.4; = p.E78Q on NM_006119.6) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV100199432; called by muse, mutect2
- FOXR1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100393016; called by muse, mutect2, varscan2
- GPR149 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.697); catalogued as rs1019744624, COSV101078713; called by muse, mutect2, varscan2
- HCFC1 | c.4621C>A p.P1541T | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100129799; called by muse, mutect2
- HEATR1 | c.1259T>C p.L420S | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.057); catalogued as COSV100857789; called by muse, mutect2
- IDO2 | c.878T>C p.L293P (on ENST00000389060; = p.L306P on NM_194294.2) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100584949; called by muse, mutect2, varscan2
- MLXIPL | c.2033C>A p.T678K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100515529; called by muse, mutect2, varscan2
- MRPS12 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as COSV99671544; called by muse, mutect2, varscan2
- MTUS2 | c.2513C>A p.P838H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99686544; called by muse, mutect2, varscan2
- NCOA2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101476053; called by muse, mutect2, varscan2
- NF1 | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV100648149; called by muse, mutect2, varscan2
- NIBAN2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs749442375, COSV100964943; called by muse, mutect2, varscan2
- P3H2 | c.1189-2A>T p.X397_splice | Splice Site (SNP) | VAF 69/231 reads (30%) | catalogued as COSV100078403; called by muse, mutect2, varscan2
- PLPPR4 | c.733A>C p.R245= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100926910; called by muse, mutect2, varscan2
- PNISR | c.1375A>C p.I459L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV100984424; called by muse, mutect2, varscan2
- POU3F3 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722446; called by muse, mutect2, varscan2
- PRF1 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV64614308; called by muse, varscan2
- RECQL4 | c.1394C>G p.T465R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99468156; called by muse, mutect2, varscan2
- RFX6 | c.1737T>A p.N579K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV100264226; called by muse, mutect2, varscan2
- RHOBTB2 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.765); catalogued as COSV52573594; called by muse, varscan2
- RIMS1 | c.3414_3415insA p.S1139Ifs*4 | Frame Shift Ins (INS) | VAF 17/73 reads (23%) | catalogued as COSV99330105; called by mutect2, pindel, varscan2
- SEC16B | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.121); catalogued as rs902343637, COSV100381107; called by muse, mutect2, varscan2
- SETDB1 | c.3764T>G p.I1255S (on ENST00000271640 / NM_001366417.1; = p.I1254S on NM_012432.4) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99645794; called by muse, mutect2, varscan2
- SLC10A5 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101594270; called by muse, mutect2, varscan2
- SMARCA1 | c.971C>A p.S324* | Nonsense Mutation (SNP) | VAF 53/241 reads (22%) | catalogued as COSV100946700; called by muse, mutect2
- SPATA6L | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as rs545196734, COSV56305509; called by muse, mutect2, varscan2
- SPDYC | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101017285; called by muse, mutect2
- SPTB | c.4703G>A p.R1568K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV101072389; called by muse, mutect2, varscan2
- SUGP2 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs375174157; called by muse, mutect2, varscan2
- TANGO6 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1258951237, COSV55769378; called by muse, mutect2, varscan2
- TBC1D15 | c.1272T>G p.F424L | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100042215; called by muse, mutect2, varscan2
- TET1 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as rs568996501, COSV101018838; called by muse, mutect2, varscan2
- TIAM2 | c.3951+2T>C p.X1317_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99265966; called by muse, mutect2, varscan2
- TLK2 | c.1703G>A p.R568Q (on ENST00000326270 / NM_001284333.2; = p.R546Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100409519; called by muse, mutect2
- TNRC6A | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.432); catalogued as COSV100170436; called by muse, mutect2, varscan2
- TNRC6A | c.4495C>A p.Q1499K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as COSV100170438; called by muse, mutect2, varscan2
- WDR20 | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100085433; called by muse, mutect2, varscan2
- ZNF280B | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV100840436; called by muse, mutect2, varscan2
- ZNF516 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1490008306, COSV71587518; called by muse, mutect2, varscan2
- ZNF564 | c.1421A>G p.E474G | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100213275; called by muse, mutect2, varscan2
- ZNF606 | c.2367G>C p.E789D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100072000, COSV58706368; called by muse, mutect2, varscan2
- ZNF606 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as rs762230096, COSV100072001; called by muse, mutect2, varscan2
- MACF1 | c.13921G>A p.A4641T (on ENST00000372915; = p.A2574T on NM_012090.5) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- RABEP1 | c.1951del p.S651Vfs*32 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- TTC23L | c.747dup p.R250* | Frame Shift Ins (INS) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- ADAM23 | c.984C>T p.S328= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as rs776991074, COSV52224635; called by muse, mutect2, varscan2
- BSN | c.4020C>G p.V1340= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99609680; called by muse, mutect2
- CACNB4 | c.735C>T p.F245= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1473191188, COSV99139425; called by muse, mutect2, varscan2
- CASR | c.1428G>T p.G476= (on ENST00000490131; = p.G553= on NM_000388.4) | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99949405; called by muse, mutect2
- CDHR2 | c.543C>A p.A181= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99992139; called by muse, mutect2, varscan2
- CLCN5 | c.2094C>A p.I698= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100260374, COSV56585534; called by muse, mutect2, varscan2
- HIVEP3 | c.291G>A p.Q97= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- HPS3 | c.66G>C p.P22= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs773089048, COSV99937613; called by muse, mutect2, varscan2
- HSP90AA1 | c.150G>C p.L50= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV100085429; called by muse, mutect2, varscan2
- IRX5 | c.1206C>G p.L402= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs747778732, COSV100315978; called by muse, mutect2
- LIMA1 | c.1665A>G p.K555= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1476649308, COSV100372692; called by muse, mutect2, varscan2
- MAGED1 | c.1770A>G p.G590= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100431800; called by muse, mutect2, varscan2
- MCAM | c.534C>T p.G178= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99877946; called by muse, mutect2, varscan2
- MRC2 | c.72C>T p.C24= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100316712; called by muse, mutect2
- NCOA3 | c.3273A>G p.K1091= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV100508127; called by muse, mutect2
- NF1 | c.1254C>T p.I418= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100648151; called by muse, varscan2
- PLEKHG7 | c.1525A>C p.R509= | Silent (SNP) | VAF 63/246 reads (26%) | catalogued as rs1355781323, COSV100760177; called by muse, mutect2, varscan2
- PLXNB3 | c.2844A>T p.R948= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100737866; called by muse, mutect2
- PPP1R12B | c.2595C>A p.A865= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99295243; called by muse, mutect2, varscan2
- STRC | c.4590G>A p.Q1530= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100294679; called by muse, mutect2, varscan2
- TIMM10 | c.138C>T p.G46= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs774100984, COSV57202113; called by muse, mutect2, varscan2
- TSEN54 | c.1170G>A p.V390= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99390444; called by muse, mutect2, varscan2
- USP44 | c.111C>A p.S37= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99312038; called by muse, mutect2, varscan2
- ZNF26 | c.37T>C p.L13= | Silent (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2
- AC092718.9 | chr16:81148159 G>A | 5'Flank (SNP) | VAF 10/42 reads (24%) | catalogued as rs753737969; called by mutect2, varscan2
- ACSL5 | c.-165G>T | 5'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100634689, COSV100634764; called by muse, mutect2
- AP000769.3 | chr11:65501801 del AA | 5'Flank (DEL) | VAF 32/170 reads (19%) | catalogued as rs752044550; called by mutect2, pindel, varscan2
- DST | c.4297-2398T>A | Intron (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99759540; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85834C>G | Intron (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SCN5A | c.612-210C>A | Intron (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100350311; called by muse, mutect2, varscan2
